Gene-level copy-number profile of tumor specimen TCGA-AA-3846-01A from TCGA case TCGA-AA-3846, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.1 years (27,057 days).
Specimen TCGA-AA-3846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6059d2ad-bd06-41d4-82c0-94e7fac770e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3846-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ad94a73-1c0a-4582-9298-0d4bf7ae9f35

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,460; copy number 3: 34,027; copy number 4: 11,827; copy number 5: 2,711; copy number 6: 2,708; copy number 12: 6; copy number 15: 25; copy number 16: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3846-01A-01D-1018-01): tumor purity 0.6, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 86 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:69,726,900–70,189,070, 6 genes, copy number 12 (within-gene range 2–12): SRSF5, SLC10A1, AL157789.1, SMOC1, RPL7AP6, SLC8A3.
- chr20:25,452,697–26,188,191, 24 genes, copy number 15 (within-gene range 6–15): NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2.
- chr20:26,188,408–26,196,891, 1 gene, copy number 15: AL121904.1.
- chr20:41,684,986–44,663,498, 55 genes, copy number 16 (within-gene range 6–16): RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
